Gene-level copy-number profile of tumor specimen TCGA-DV-A4VX-01A from TCGA case TCGA-DV-A4VX, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 59.3 years (21,670 days).
Specimen TCGA-DV-A4VX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.82f204d0-0f7c-4494-8f2e-8f6be61db7d1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DV-A4VX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-DV-A4VX-01A|TCGA-DV-A4VX-10B); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/762b5fbb-e355-4f34-8422-16b4c7c574f6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,753; copy number 2: 30,947; copy number 3: 20,829; copy number 4: 284; copy number 5: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DV-A4VX-01A-11D-A25U-01): tumor purity 0.72, ploidy 2.3, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:90,135,712–90,926,597, 7 genes, copy number 5: RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410.

Autosomal genes at a single copy (total copy number 1): 5,372. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
